Somatic mutation profile of tumor specimen TARGET-30-PAULNF-01A (aliquot TARGET-30-PAULNF-01A-01D) from TARGET case TARGET-30-PAULNF, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.9 years (1,061 days).
Specimen TARGET-30-PAULNF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbc556d4-cc84-49ab-a01a-0ae1dbce2446.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAULNF-10A (Blood Derived Normal), aliquot TARGET-30-PAULNF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cbda1ef-f21a-4b11-8660-4485a01e0678

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.2080G>T p.D694Y | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57669767, COSV57669807; called by muse, mutect2, varscan2
- DNAH2 | c.4532C>G p.T1511R | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.102); catalogued as COSV66727948; called by muse, mutect2, varscan2
- RELN | c.2763G>T p.Q921H | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.983); catalogued as COSV59035962; called by muse, mutect2, varscan2
- ATM | c.5035G>A p.G1679S | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
